Somatic mutation profile of tumor specimen TCGA-GS-A9TQ-01A (aliquot TCGA-GS-A9TQ-01A-11D-A382-10) from TCGA case TCGA-GS-A9TQ, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 69.2 years (25,292 days).
Specimen TCGA-GS-A9TQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a5263a6-eab6-4187-bce2-995d2d22fec3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9TQ-10A (Blood Derived Normal), aliquot TCGA-GS-A9TQ-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bc95e7a-4253-42f7-8fc7-87e9704fc3da

The open-access MAF lists 156 somatic variants for this specimen: 111 protein-altering or splice-affecting, 37 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 37, Nonsense Mutation 8, Intron 4, Splice Site 3, Frame Shift Ins 3, Frame Shift Del 3, Splice Region 2, 3'Flank 2, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.2209C>T p.L737F | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs768750286, COSV100601444; called by muse, mutect2, varscan2
- ADGRG1 | c.1879T>G p.F627V | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101113290; called by muse, mutect2, varscan2
- ADGRL2 | c.1943C>A p.A648D (on ENST00000370717 / NM_001366005.1; = p.A635D on NM_012302.4) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99586682; called by muse, mutect2, varscan2
- ANLN | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as COSV56074068, COSV99731644; called by muse, mutect2, varscan2
- ANO1 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 16/95 reads (17%) | catalogued as COSV60283632; called by muse, mutect2, varscan2
- ANO5 | c.176T>G p.L59R | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV61087605; called by muse, mutect2, varscan2
- ARID1A | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV61377864; called by muse, mutect2, varscan2
- AXL | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs962997099, COSV56564670; called by muse, mutect2, varscan2
- B3GNT8 | c.254G>C p.S85T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99524363; called by muse, mutect2, varscan2
- BCL2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61377942, COSV61382824; called by muse, mutect2, varscan2
- BCL2 | c.7C>G p.H3D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV61390615; called by muse, varscan2
- BCL7A | c.32G>C p.R11T | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV55846523, COSV55851191; called by muse, mutect2
- BHLHA15 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as rs780454116, COSV99805766; called by muse, varscan2
- BTK | c.945T>G p.Y315* | Nonsense Mutation (SNP) | VAF 33/127 reads (26%) | catalogued as CM980271, COSV100437231; called by muse, mutect2, varscan2
- C4A | c.3365C>T p.P1122L | Missense Mutation (SNP) | VAF 72/861 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71177579; called by muse, mutect2
- CCDC88B | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.996); catalogued as rs764082188, COSV57265537; called by muse, mutect2, varscan2
- CDH18 | c.1015A>T p.K339* | Nonsense Mutation (SNP) | VAF 59/245 reads (24%) | catalogued as COSV99931245; called by muse, mutect2, varscan2
- CILP2 | c.2429C>T p.T810I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.347); catalogued as COSV99364206; called by muse, mutect2, varscan2
- CREBBP | c.4223G>A p.C1408Y | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52119540; called by muse, mutect2, varscan2
- CSN3 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100515229; called by muse, mutect2, varscan2
- CYP11B1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200559974, COSV99454314; called by muse, mutect2, varscan2
- DHRS3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs200434720; called by mutect2, varscan2
- DIPK1C | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs371974579, COSV59724602; called by muse, mutect2, varscan2
- DNAJC18 | c.40+2T>G p.X14_splice | Splice Site (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100122021; called by muse, mutect2, varscan2
- DOC2A | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100451124; called by muse, mutect2, varscan2
- EGR1 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs749068859, COSV99525214; called by muse, varscan2
- ENAM | c.3175G>A p.G1059S | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV101252858; called by muse, mutect2, varscan2
- ENTPD5 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206418978, COSV58220816; called by muse, mutect2, varscan2
- EXTL3 | c.2209A>T p.T737S | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99593628; called by muse, mutect2, varscan2
- FAM161B | c.728G>A p.R243H (on ENST00000651776; = p.R180H on NM_152445.3) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750587720, COSV99679476; called by muse, varscan2
- FAM178B | c.1684A>G p.R562G (on ENST00000490605 / NM_001122646.3; = p.R2G on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100013559; called by mutect2, varscan2
- FANCD2 | c.1560T>G p.Y520* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99810099; called by muse, mutect2, varscan2
- FAU | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.682); catalogued as COSV99657997; called by muse, mutect2, varscan2
- FBXW12 | c.663A>C p.L221F | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99601385; called by muse, mutect2, varscan2
- FKBP9 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs369631041; called by muse, mutect2, varscan2
- FLG | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs139321371, COSV100910484; called by muse, mutect2, varscan2
- FLVCR1 | c.1331C>A p.P444H | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100874981; called by muse, mutect2, varscan2
- GNA13 | c.767T>G p.L256R | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101457390, COSV71475049; called by muse, mutect2
- GNA13 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101457393; called by muse, mutect2, varscan2
- H1-4 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV56800595; called by muse, mutect2, varscan2
- H1-4 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs777376445, COSV56801032; called by muse, varscan2
- H1-4 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV56802372, COSV99175186; called by muse, varscan2
- H2AC21 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV100479632; called by muse, varscan2
- HELZ2 | c.5824G>C p.A1942P (on ENST00000467148 / NM_001037335.2; = p.A1373P on NM_033405.3) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.286); catalogued as COSV101427502; called by muse, mutect2, varscan2
- HIF1AN | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.438); catalogued as COSV100142507; called by muse, mutect2, varscan2
- HKDC1 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398340797, COSV100664308; called by muse, mutect2, varscan2
- HLA-A | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as rs72558105, COSV65143634; called by muse, varscan2
- HPSE2 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1465062636, COSV100984620; called by muse, mutect2, varscan2
- IBA57 | c.305T>G p.V102G | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs759005478, COSV100812743; ClinVar: uncertain significance; called by mutect2, varscan2
- IGHG1 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.167); catalogued as rs587667988; called by muse, mutect2, varscan2
- IGHV1-24 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs554708298; called by muse, varscan2
- IGHV1-24 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs112338861; called by muse, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IL6ST | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273974875, COSV61140692; called by muse, mutect2, varscan2
- INPP5F | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs769991503, COSV100739932; called by muse, mutect2, varscan2
- ITGA3 | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as rs757812706, COSV99143186; called by muse, mutect2, varscan2
- JMJD1C | c.4489A>G p.S1497G | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1407847287, COSV59518104; called by muse, mutect2, varscan2
- KCNN1 | c.1405T>C p.S469P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV99715524; called by muse, mutect2, varscan2
- KIF3C | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV99266904; called by muse, mutect2, varscan2
- KMT2D | c.15325T>C p.C5109R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99976597; called by muse, mutect2
- LARP1B | c.1161+2T>C p.X387_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99217633; called by muse, mutect2, varscan2
- LPIN2 | c.682T>C p.W228R | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99857828; called by muse, mutect2
- MAOB | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs980435225, COSV100955858, COSV100956289; called by muse, mutect2, varscan2
- MARK1 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs535686841, COSV100856973; called by muse, varscan2
- MAZ | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs747608454, COSV99360738; called by mutect2, varscan2
- MYO1A | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767218992, COSV55655710; called by mutect2, varscan2
- MYO9A | c.6854G>A p.R2285H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs779156758, COSV61858604; called by muse, mutect2, varscan2
- NEK10 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774551711, COSV55356403, COSV99834621; called by muse, mutect2, varscan2
- OR52A1 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100200379; called by muse, mutect2, varscan2
- OR5R1 | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs776387543, COSV100393203; called by muse, mutect2, varscan2
- PCDHA5 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65354060; called by muse, mutect2, varscan2
- PCLO | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 98/409 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100426291; called by muse, mutect2, varscan2
- PLEKHA6 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs780262446, COSV99691357, COSV99691984; called by muse, mutect2, varscan2
- POLD1 | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV70954931; called by mutect2, varscan2
- PPP1R3A | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 36/124 reads (29%) | catalogued as rs1418546233, COSV99491696; called by muse, mutect2, varscan2
- PRPF19 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401369134, COSV99920405; called by muse, mutect2, varscan2
- RAF1 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV99311633; called by muse, mutect2, varscan2
- RGL3 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV100992805; called by muse, mutect2, varscan2
- RPH3A | c.832C>T p.P278S (on ENST00000389385 / NM_001143854.2; = p.P274S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV101231751; called by muse, mutect2, varscan2
- RPL37 | c.6G>A p.T2= | Splice Region (SNP) | VAF 11/55 reads (20%) | catalogued as rs780838417, COSV57038839; called by muse, mutect2, varscan2
- RYR2 | c.7996C>A p.L2666M | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.093); catalogued as rs370333448, COSV100767168; called by muse, mutect2, varscan2
- RYR2 | c.12493G>A p.V4165I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.977); catalogued as COSV100767169; called by muse, mutect2, varscan2
- SGK1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV52810268, COSV99397580; called by muse, mutect2, varscan2
- SLC2A5 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.281); catalogued as COSV101072611; called by mutect2, varscan2
- SLC45A1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs147681901; called by mutect2, varscan2
- SNRPN | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs372352489; called by muse, mutect2, varscan2
- SNX27 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 24/140 reads (17%) | catalogued as COSV100918963; called by muse, mutect2, varscan2
- SOGA1 | c.2924A>G p.N975S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.082); catalogued as rs754144105, COSV99412435; called by muse, mutect2, varscan2
- SPTBN4 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1414794752, COSV58947384; called by muse, mutect2, varscan2
- STIM2 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs778636017, COSV52836501; called by muse, mutect2, varscan2
- TBX18 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV63738627; called by muse, mutect2, varscan2
- TFAP2B | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53827182, COSV53828173; called by muse, mutect2, varscan2
- TRANK1 | c.2626G>T p.A876S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV100080934; called by muse, mutect2, varscan2
- TRMT13 | c.764A>T p.E255V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV100734284, COSV61583038; called by muse, mutect2, varscan2
- UBR4 | c.4481T>A p.L1494* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100919954; called by muse, mutect2, varscan2
- VEPH1 | c.1997T>G p.F666C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100747249; called by muse, mutect2, varscan2
- WFDC11 | c.181T>A p.C61S | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100180615; called by muse, mutect2, varscan2
- WRAP53 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99357588; called by muse, mutect2, varscan2
- ZNF236 | c.1723T>A p.F575I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99468536; called by muse, mutect2, varscan2
- ZNF286A | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV101224711; called by muse, mutect2, varscan2
- ZNF385D | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99872688; called by muse, mutect2, varscan2
- ZNF551 | c.81+2T>A p.X27_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99989653; called by muse, mutect2, varscan2
- CNPY4 | c.312del p.E105Sfs*6 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel
- ENTHD1 | c.848_851del p.L283Qfs*11 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- IGHV1-24 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, varscan2
- PLCB1 | c.246+6_246+7insTCCCAGGA | Splice Region (INS) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- PLEKHG6 | c.1830_1831del p.R611Sfs*58 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- SETX | c.332_338dup p.L114Sfs*5 | Frame Shift Ins (INS) | VAF 38/82 reads (46%) | called by mutect2, varscan2
- SPTBN5 | c.2684_2687dup p.M896Ifs*33 | Frame Shift Ins (INS) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- SYNE1 | c.5943dup p.A1982Sfs*14 (on ENST00000367255 / NM_182961.4; = p.A1989Sfs*14 on NM_033071.3) | Frame Shift Ins (INS) | VAF 25/101 reads (25%) | called by mutect2, pindel, varscan2
- TRADD | c.641_658del p.L214_Q219del | In Frame Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel
- ACP7 | c.1194G>A p.T398= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1345264616, COSV58701567; called by muse, mutect2, varscan2
- ANO2 | c.339C>T p.G113= (on ENST00000356134 / NM_001278597.3; = p.G117= on NM_001278596.3) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100499400; called by muse, mutect2, varscan2
- AOC1 | c.1941C>T p.P647= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs375543270, COSV100710541; called by muse, mutect2, varscan2
- ARHGEF11 | c.1080G>A p.L360= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs1444976048, COSV100809530; called by muse, mutect2, varscan2
- B3GALNT2 | c.384G>A p.A128= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1049290415, COSV100010008; called by muse, mutect2, varscan2
- BIRC6 | c.12969T>C p.L4323= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV101427735; called by muse, mutect2, varscan2
- C10orf90 | c.684C>T p.D228= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as rs938927737, COSV99502827; called by muse, mutect2, varscan2
- CCNJL | c.1290C>T p.T430= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs377553131; called by muse, mutect2, varscan2
- DDX60L | c.2158C>T p.L720= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV99486729; called by muse, mutect2, varscan2
- DNAJC11 | c.1170C>T p.F390= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99601736; called by muse, varscan2
- DSP | c.7459C>T p.L2487= | Silent (SNP) | VAF 64/85 reads (75%) | catalogued as COSV101131154; called by muse, mutect2, varscan2
- FANCA | c.270T>A p.S90= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV101224642; called by muse, mutect2
- FAT1 | c.4680G>A p.P1560= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs370954148; called by muse, mutect2, varscan2
- FFAR4 | c.576G>T p.S192= | Silent (SNP) | VAF 40/332 reads (12%) | catalogued as COSV65179838; called by muse, mutect2, varscan2
- FKBP10 | c.594C>T p.G198= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs782631088, COSV58637598; called by muse, mutect2, varscan2
- FNDC1 | c.1044G>A p.T348= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs761535434, COSV99794587; called by muse, mutect2, varscan2
- GZF1 | c.867G>A p.E289= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100582339; called by muse, mutect2, varscan2
- IGHV1-24 | c.168G>C p.V56= | Silent (SNP) | VAF 14/67 reads (21%) | called by muse, varscan2
- IGHV1-24 | c.67C>T p.L23= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs111257793; called by muse, varscan2
- IGHV2-70 | c.186A>G p.P62= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as rs997215308; called by muse, varscan2
- IGLV3-1 | c.102A>C p.G34= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs185369291; called by muse, varscan2
- ITFG1 | c.180G>A p.K60= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100065131; called by muse, mutect2, varscan2
- KAAG1 | c.195C>T p.G65= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs759867603, COSV99219654; called by mutect2, varscan2
- KIF5B | c.2373A>G p.K791= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as COSV100191208; called by muse, mutect2, varscan2
- LSR | c.1767G>A p.R589= (on ENST00000361790; = p.R570= on NM_015925.6) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1212901063, COSV99723225; called by mutect2, varscan2
- MFAP3L | c.81C>T p.T27= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs756293670, COSV100852600; called by muse, mutect2, varscan2
- MIA3 | c.3315G>A p.E1105= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100719202; called by muse, mutect2, varscan2
- MUC4 | c.14499G>A p.T4833= (on ENST00000463781 / NM_018406.7; = p.T597= on NM_004532.6) | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100203187; called by muse, mutect2, varscan2
- MYT1L | c.3408G>A p.P1136= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs780878610, COSV101216728; called by muse, mutect2, varscan2
- OR2T2 | c.231C>T p.I77= | Silent (SNP) | VAF 44/600 reads (7%) | catalogued as rs762445074, COSV100737665, COSV61618655; called by muse, mutect2
- PDCD11 | c.2940C>G p.L980= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV100874212; called by muse, mutect2, varscan2
- PRKD1 | c.2545C>A p.R849= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV100118987, COSV59564070; called by muse, mutect2, varscan2
- RIN3 | c.2811C>T p.D937= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs1350216660, COSV99378236; called by muse, mutect2, varscan2
- SH3D19 | c.1206T>G p.R402= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100455469; called by muse, mutect2, varscan2
- SPO11 | c.615G>A p.S205= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs757585150, COSV100625591; called by muse, mutect2, varscan2
- UCKL1 | c.1170G>A p.A390= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs751969751, COSV100694112; called by muse, mutect2, varscan2
- ZNF488 | c.264G>A p.P88= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs149783300; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149797 C>T | 5'Flank (SNP) | VAF 18/56 reads (32%) | catalogued as rs377031590; called by muse, mutect2, varscan2
- DST | c.4296+3957A>C | Intron (SNP) | VAF 30/221 reads (14%) | catalogued as COSV99749584; called by muse, mutect2
- IGHG1 | chr14:105737779 T>C | 3'Flank (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- IGHG1 | chr14:105737837 C>T | 3'Flank (SNP) | VAF 7/52 reads (13%) | catalogued as rs750661555; called by muse, varscan2
- MACF1 | c.15832-11035A>C | Intron (SNP) | VAF 35/159 reads (22%) | catalogued as COSV99240451; called by muse, mutect2
- NCOA1 | c.4156-115G>A | Intron (SNP) | VAF 21/140 reads (15%) | catalogued as COSV99944902; called by muse, mutect2, varscan2
- SAMD14 | c.823-69C>T | Intron (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99142893; called by muse, mutect2, varscan2
- TMEM132E | chr17:34578889 C>A | 5'Flank (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
